Gene-level copy-number profile of tumor specimen TCGA-DU-6401-01A from TCGA case TCGA-DU-6401, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.7 years (11,595 days).
Specimen TCGA-DU-6401-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.cd195673-7373-417f-a34f-10961287acc2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-6401-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/66bd4b5b-0ab5-413e-b2e2-0860a98da214

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 239; copy number 1: 7,506; copy number 2: 52,069; copy number 3: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-6401-01A-11D-1704-01): tumor purity 0.38, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:95,504,182–98,400,869, 25 genes (within-gene range 0–2): CYCSP17, MANEA-DT, MANEA, AL607077.1, AL034348.1, KRT18P50, FUT9, UFL1-AS1, RN7SL797P, UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32, MMS22L, AL589740.1, AL080316.1, MIR2113.
- chr17:7,549,058–9,576,591, 97 genes (broad region; genes not listed).
- chr17:9,589,902–9,590,482, 1 gene: RPL19P18.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,774. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
